Somatic mutation profile of tumor specimen TCGA-66-2757-01A (aliquot TCGA-66-2757-01A-01W-0877-08) from TCGA case TCGA-66-2757, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 65.7 years (24,014 days).
Specimen TCGA-66-2757-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebc6e80f-cd5d-47b1-b81d-f2264d3cee59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2757-11A (Solid Tissue Normal), aliquot TCGA-66-2757-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/312e2b4e-356e-4838-adaf-fb14b33a519f

The open-access MAF lists 254 somatic variants for this specimen: 198 protein-altering or splice-affecting, 50 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 50, Splice Site 11, Nonsense Mutation 9, Frame Shift Del 6, Intron 4, Frame Shift Ins 3, RNA 1, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.332T>G p.L111R | Missense Mutation (SNP) | VAF 105/154 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519997, CX942126, COSV52676090, COSV52699193, COSV52985195; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.3199C>A p.L1067I | Missense Mutation (SNP) | VAF 100/279 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV59391189; called by muse, mutect2, varscan2
- ABCD1 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs782159028, COSV54387281; called by muse, mutect2, varscan2
- ABCG1 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 66/82 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV59209161; called by muse, mutect2, varscan2
- ADGRG4 | c.3207G>T p.Q1069H | Missense Mutation (SNP) | VAF 1575/4006 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV54964228; called by muse, mutect2, varscan2
- ADRB2 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.479); catalogued as COSV60006085; called by muse, mutect2, varscan2
- ALLC | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV52993506, COSV52997535; called by muse, mutect2, varscan2
- ANGPTL5 | c.694T>C p.Y232H | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV57534291; called by muse, mutect2, varscan2
- AQP12A | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422147404, COSV61837607; called by muse, mutect2, varscan2
- AQP12A | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61837611; called by muse, mutect2, varscan2
- ARHGEF35 | c.1156A>G p.R386G | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100967765; called by muse, mutect2, varscan2
- ARHGEF4 | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 111/224 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV58127976; called by muse, mutect2, varscan2
- ATG7 | c.2028A>T p.L676F | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61615013; called by muse, mutect2, varscan2
- ATP8B4 | c.3104T>C p.I1035T | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV52722195; called by muse, mutect2, varscan2
- BAAT | c.938T>C p.I313T | Missense Mutation (SNP) | VAF 102/244 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs1366423369, COSV52290511; called by muse, mutect2, varscan2
- BTBD3 | c.679G>T p.V227L | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV54780946; called by muse, mutect2, varscan2
- C19orf44 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV55614151; called by muse, mutect2, varscan2
- CAMK1G | c.1376C>G p.A459G | Missense Mutation (SNP) | VAF 98/370 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV50524888; called by muse, mutect2
- CCDC185 | c.1708C>A p.Q570K | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as COSV64821641; called by muse, mutect2, varscan2
- CDH10 | c.174G>T p.W58C | Missense Mutation (SNP) | VAF 104/392 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52591050, COSV52593301, COSV52593638; called by muse, mutect2, varscan2
- CDH18 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868527442, COSV56907663, COSV56951940; called by muse, mutect2, varscan2
- CDH18 | c.312C>G p.D104E | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs368155280, COSV56951957; called by muse, mutect2, varscan2
- CEP162 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 82/255 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as COSV57623118; called by muse, mutect2, varscan2
- CHRNA1 | c.52G>T p.V18F | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.197); catalogued as COSV53682806, COSV53684609; called by muse, mutect2, varscan2
- CLCN6 | c.2397G>A p.M799I | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.549); catalogued as COSV56742491; called by muse, mutect2, varscan2
- CLSTN2 | c.110-1G>T p.X37_splice | Splice Site (SNP) | VAF 42/144 reads (29%) | catalogued as rs1292488639, COSV71724013; called by muse, mutect2, varscan2
- CPS1 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51821267, COSV99242488; called by muse, mutect2, varscan2
- CPT1C | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54921577; called by muse, mutect2, varscan2
- CSMD2 | c.6181G>A p.D2061N | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749635413, COSV53905822, COSV53951061; called by muse, mutect2, varscan2
- CXorf56 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 174/533 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.39); catalogued as COSV57439023; called by muse, mutect2, varscan2
- DCAKD | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 120/263 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs755858662, COSV60203146; called by muse, mutect2, varscan2
- DDX11 | c.437A>G p.Q146R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV52509237; called by muse, mutect2
- DHX36 | c.853G>T p.G285C | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100274077, COSV57676224; called by muse, mutect2, varscan2
- DLC1 | c.3862G>A p.E1288K (on ENST00000276297 / NM_001348081.2; = p.E851K on NM_006094.5) | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs377705483; called by muse, mutect2, varscan2
- DNTT | c.318G>A p.W106* | Nonsense Mutation (SNP) | VAF 100/142 reads (70%) | catalogued as COSV64522857; called by muse, mutect2, varscan2
- DNTTIP1 | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.166); catalogued as COSV54755677; called by muse, mutect2
- EP400 | c.9055A>T p.T3019S | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV57783218; called by muse, mutect2, varscan2
- EPHA6 | c.3333C>G p.S1111R | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV67589653; called by muse, mutect2, varscan2
- EPRS1 | c.3694A>C p.S1232R | Missense Mutation (SNP) | VAF 26/786 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV65101018; called by muse, mutect2
- ERICH3 | c.4289G>T p.G1430V | Missense Mutation (SNP) | VAF 271/714 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV58615187; called by muse, mutect2, varscan2
- FAM47A | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 38/106 reads (36%) | catalogued as COSV100649716, COSV60499181; called by muse, mutect2, varscan2
- FAT3 | c.4544C>T p.T1515I | Missense Mutation (SNP) | VAF 317/1010 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV53159483; called by muse, mutect2, varscan2
- FBN2 | c.3294C>G p.C1098W | Missense Mutation (SNP) | VAF 298/363 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV52537825; called by muse, mutect2, varscan2
- FBXL20 | c.1053C>A p.C351* | Nonsense Mutation (SNP) | VAF 141/266 reads (53%) | catalogued as COSV52897795, COSV52902984; called by muse, mutect2, varscan2
- FGF10 | c.430-2A>T p.X144_splice | Splice Site (SNP) | VAF 86/240 reads (36%) | catalogued as COSV99240757; called by muse, mutect2, varscan2
- FGF18 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV51128736; called by muse, mutect2, varscan2
- FOXJ2 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 209/490 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV50822712; called by muse, mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 14/103 reads (14%) | catalogued as rs752538869; called by mutect2, varscan2
- FZD3 | c.1853C>A p.T618K | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.024); catalogued as COSV53537262; called by muse, mutect2, varscan2
- GABRA2 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.066); catalogued as COSV100734232, COSV62918399; called by muse, mutect2, varscan2
- GABRA3 | c.455T>A p.F152Y | Missense Mutation (SNP) | VAF 146/408 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as COSV64803769; called by muse, mutect2, varscan2
- GABRQ | c.748+2T>A p.X250_splice | Splice Site (SNP) | VAF 115/282 reads (41%) | catalogued as COSV64781490, COSV64783590; called by muse, mutect2, varscan2
- GALNTL5 | c.1087A>G p.K363E | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV67180936; called by muse, mutect2, varscan2
- GJA8 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 70/213 reads (33%) | catalogued as COSV53790201; called by muse, mutect2, varscan2
- GPNMB | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 82/128 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51698036, COSV51700439; called by muse, mutect2, varscan2
- GPR17 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55756702; called by muse, mutect2, varscan2
- GPR83 | c.967A>G p.N323D | Missense Mutation (SNP) | VAF 371/618 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV54720266; called by muse, mutect2, varscan2
- GRIK2 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV59729281, COSV59761825; called by muse, mutect2, varscan2
- GSTA1 | c.381A>C p.K127N | Missense Mutation (SNP) | VAF 52/1025 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV58016526; called by muse, mutect2
- GSTM2 | c.23G>A p.W8* | Nonsense Mutation (SNP) | VAF 58/158 reads (37%) | catalogued as COSV99598279, COSV99598288; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 143/321 reads (45%) | catalogued as COSV57133492; called by muse, mutect2, varscan2
- HPS5 | c.1117G>T p.A373S (on ENST00000349215 / NM_181507.2; = p.A259S on NM_007216.4) | Missense Mutation (SNP) | VAF 195/445 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100752337, COSV61687897; called by muse, mutect2, varscan2
- HTR2C | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 143/489 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194076654, COSV52220873; called by muse, mutect2, varscan2
- ICAM4 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV53426656; called by muse, mutect2, varscan2
- IGLV8-61 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV66503347; called by muse, mutect2
- IL1RAPL1 | c.1858C>A p.R620S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.283); catalogued as COSV100147047, COSV100148571, COSV56290459; called by muse, mutect2, varscan2
- IMMT | c.1217C>G p.A406G | Missense Mutation (SNP) | VAF 42/410 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV54487249, COSV54489291; called by muse, mutect2
- INPP5E | c.1200G>C p.Q400H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV65497024; called by muse, mutect2, varscan2
- IPO4 | c.1156C>G p.H386D | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV55781414; called by muse, mutect2, varscan2
- ITGB1BP2 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 177/457 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1030739067, COSV52139812; called by muse, mutect2, varscan2
- JPH2 | c.211G>T p.G71W | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60697781; called by muse, mutect2, varscan2
- KCNT1 | c.2423C>G p.S808C (on ENST00000488444; = p.S827C on NM_020822.3) | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV53701968, COSV53708587; called by muse, mutect2, varscan2
- KCTD8 | c.1210C>A p.P404T | Missense Mutation (SNP) | VAF 193/494 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.22); catalogued as COSV63594466; called by muse, mutect2, varscan2
- KDM5A | c.4208C>T p.S1403F | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV66994385; called by muse, mutect2, varscan2
- KDR | c.2630G>T p.S877I | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55773415, COSV55777066; called by muse, mutect2, varscan2
- KIAA0408 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 230/518 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV100846981, COSV64109355; called by muse, mutect2, varscan2
- KIF1B | c.4371G>A p.M1457I (on ENST00000377086 / NM_001365952.1; = p.M1411I on NM_015074.3) | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV55814103; called by muse, mutect2
- KLHL25 | c.1040dup p.R348Qfs*19 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs760548052; called by pindel, varscan2
- LAMA3 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV58076645; called by muse, mutect2, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 36/237 reads (15%) | catalogued as rs746133895; called by mutect2, varscan2
- LRRTM4 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV69138812, COSV69141526; called by muse, mutect2, varscan2
- MACROD1 | c.786+1G>T p.X262_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | catalogued as COSV55365850; called by mutect2, varscan2
- MAGEA10 | c.746C>A p.A249E | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV54885482; called by muse, mutect2, varscan2
- MAGEB2 | c.39G>C p.E13D | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66781541; called by muse, mutect2, varscan2
- MAP3K12 | c.31T>A p.S11T | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); catalogued as rs1044044074; called by muse, mutect2
- MET | c.2731-1G>C p.X911_splice | Splice Site (SNP) | VAF 57/139 reads (41%) | catalogued as COSV59257663; called by muse, mutect2, varscan2
- MGAM | c.4493A>T p.Q1498L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV72075380; called by muse, mutect2, varscan2
- MPP3 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 108/269 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV68199050; called by muse, mutect2, varscan2
- MSH6 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 216/549 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV52285560; called by muse, mutect2, varscan2
- MUC16 | c.21606C>G p.D7202E | Missense Mutation (SNP) | VAF 226/536 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.047); catalogued as COSV67485621; called by muse, mutect2, varscan2
- MUC17 | c.1372C>A p.P458T | Missense Mutation (SNP) | VAF 340/790 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV60299841; called by mutect2, varscan2
- MYH15 | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 196/726 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV56304892, COSV56317342; called by muse, mutect2, varscan2
- MYL1 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0.101); catalogued as COSV58974035; called by muse, mutect2, varscan2
- MYL12B | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 281/660 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV52899087; called by muse, mutect2, varscan2
- NAMPT | c.1268A>G p.K423R | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55996281; called by muse, mutect2, varscan2
- NCBP2L | c.129G>T p.M43I | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100966505; called by muse, mutect2, varscan2
- NCS1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV64963412; called by muse, mutect2, varscan2
- NELL1 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV54311160; called by muse, mutect2, varscan2
- NES | c.4407G>C p.W1469C | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV63962455; called by muse, mutect2, varscan2
- NLRP13 | c.1913T>C p.L638P | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61623676; called by muse, mutect2, varscan2
- NOS1AP | c.425G>C p.R142T | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62638962; called by muse, mutect2, varscan2
- NPAS3 | c.172G>A p.D58N (on ENST00000356141 / NM_001164749.2; = p.D28N on NM_022123.3) | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.66); PolyPhen benign (0.159); catalogued as COSV58100625, COSV58104910; called by muse, mutect2, varscan2
- NR4A1 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV54486715; called by muse, mutect2, varscan2
- NRAP | c.167+1G>T p.X56_splice | Splice Site (SNP) | VAF 29/44 reads (66%) | catalogued as COSV63492642, COSV63493236; called by muse, mutect2, varscan2
- OLFM2 | c.375G>T p.R125S | Missense Mutation (SNP) | VAF 109/235 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV53432949; called by muse, mutect2, varscan2
- OLFML2A | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.86); PolyPhen probably damaging (1); catalogued as rs751418527, COSV56585091; called by muse, mutect2, varscan2
- OR10G4 | c.143G>T p.R48M | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV100305049; called by muse, mutect2
- OR2A5 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 123/317 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV68739031; called by muse, mutect2, varscan2
- OR4K5 | c.884A>T p.K295M | Missense Mutation (SNP) | VAF 110/413 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as COSV60004834; called by muse, mutect2, varscan2
- OR4X2 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 20/459 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56584789; called by muse, mutect2
- OR51B2 | c.230C>G p.P77R | Missense Mutation (SNP) | VAF 136/339 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60917466; called by muse, mutect2, varscan2
- OR6K3 | c.198G>C p.R66S (on ENST00000368146; = p.R50S on NM_001005327.2) | Missense Mutation (SNP) | VAF 98/291 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV63746286; called by muse, mutect2, varscan2
- OR7D2 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.014); catalogued as COSV60139969, COSV60140944; called by muse, mutect2, varscan2
- OR8G5 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 129/228 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100422529; called by muse, mutect2, varscan2
- OR8H3 | c.917A>T p.Q306L | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as COSV57910896; called by muse, mutect2
- OSBPL11 | c.120C>A p.S40R | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.086); catalogued as COSV56175877; called by muse, mutect2, varscan2
- PAPLN | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.386); catalogued as COSV53722154; called by muse, mutect2
- PCARE | c.327C>A p.H109Q | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV59057023; called by muse, mutect2, varscan2
- PCDHA1 | c.1570G>T p.D524Y | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65376288; called by muse, mutect2, varscan2
- PCDHB8 | c.996C>A p.C332* | Nonsense Mutation (SNP) | VAF 12/193 reads (6%) | catalogued as COSV50804795; called by muse, mutect2
- PCDHGB2 | c.1924C>A p.L642M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54010054; called by muse, mutect2, varscan2
- PCDHGB5 | c.1904G>C p.R635P | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54010066; called by muse, mutect2, varscan2
- PDZRN4 | c.2300C>A p.T767N (on ENST00000402685 / NM_001164595.2; = p.T509N on NM_013377.4) | Missense Mutation (SNP) | VAF 98/247 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as COSV54213176; called by muse, mutect2, varscan2
- PHYHIP | c.311G>T p.W104L | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.619); catalogued as COSV58689212; called by muse, mutect2, varscan2
- PLCB1 | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62063857; called by muse, mutect2, varscan2
- PLXNA3 | c.4630C>A p.Q1544K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV63755168; called by muse, mutect2, varscan2
- PLXNB1 | c.6007G>C p.D2003H | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56489282, COSV56493240; called by muse, mutect2, varscan2
- POLA1 | c.1070-1G>T p.X357_splice | Splice Site (SNP) | VAF 125/297 reads (42%) | catalogued as COSV66889820; called by muse, mutect2, varscan2
- PPM1G | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 90/240 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59771220; called by muse, mutect2, varscan2
- PRKN | c.1041G>T p.Q347H | Missense Mutation (SNP) | VAF 155/308 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.643); catalogued as COSV58198078, COSV58251060; called by muse, mutect2, varscan2
- PRUNE2 | c.8182C>A p.P2728T | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV65046214, COSV65047843; called by muse, mutect2, varscan2
- PSMB8 | c.148-1G>T p.X50_splice (on ENST00000374882 / NM_148919.4; = p.X46_splice on NM_004159.5) | Splice Site (SNP) | VAF 21/121 reads (17%) | catalogued as COSV62754449, COSV62755500; called by muse, mutect2, varscan2
- RAB40A | c.487A>G p.I163V | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs1398173695, COSV100420885, COSV58491888; called by muse, mutect2
- RBM47 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 92/282 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55934868; called by muse, mutect2, varscan2
- RETNLB | c.209-1G>T p.X70_splice | Splice Site (SNP) | VAF 89/341 reads (26%) | catalogued as COSV99848837; called by muse, mutect2, varscan2
- RFX7 | c.2492A>T p.H831L (on ENST00000559447 / NM_001368074.1; = p.H928L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV57967463, COSV57969658; called by muse, varscan2
- RIMS4 | c.18C>A p.S6R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV65720536; called by muse, mutect2
- RLIM | c.591A>T p.E197D | Missense Mutation (SNP) | VAF 160/361 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV60328524; called by muse, mutect2, varscan2
- RNASEL | c.2203G>T p.G735W | Missense Mutation (SNP) | VAF 75/282 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.157); catalogued as COSV62377715; called by muse, mutect2, varscan2
- RNF34 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63443239; called by muse, mutect2, varscan2
- RYR1 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs923613797, COSV62107262; called by muse, mutect2, varscan2
- SASH3 | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV63556529; called by muse, mutect2, varscan2
- SCML2 | c.2063G>T p.C688F | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52624213; called by muse, mutect2, varscan2
- SCN3A | c.2206G>A p.V736M | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV51820603; called by muse, mutect2, varscan2
- SCN4A | c.5058G>T p.E1686D | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV71128567; called by muse, mutect2, varscan2
- SEC16A | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV51537628; called by muse, mutect2, varscan2
- SELP | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 299/753 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55256598; called by muse, mutect2, varscan2
- SEMA6D | c.3175G>C p.V1059L (on ENST00000316364 / NM_153618.2; = p.V997L on NM_020858.2) | Missense Mutation (SNP) | VAF 277/626 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV60382301; called by muse, mutect2, varscan2
- SEZ6L2 | c.2216T>C p.L739P (on ENST00000308713 / NM_001114099.3; = p.L669P on NM_012410.4) | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58102654; called by muse, mutect2, varscan2
- SIGLEC7 | c.630C>A p.H210Q | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV58315338, COSV58317390; called by muse, mutect2, varscan2
- SLAMF6 | c.182C>A p.S61Y | Missense Mutation (SNP) | VAF 230/573 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); catalogued as COSV63587941; called by muse, mutect2, varscan2
- SLC22A14 | c.1597A>G p.I533V | Missense Mutation (SNP) | VAF 54/78 reads (69%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs749090976, COSV56198436, COSV56198970; called by muse, mutect2, varscan2
- SLC25A34 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53818222; called by muse, mutect2, varscan2
- SLC5A8 | c.794A>G p.Q265R | Missense Mutation (SNP) | VAF 71/224 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV73311077; called by muse, mutect2, varscan2
- SLCO1B3 | c.628+2T>A p.X210_splice | Splice Site (SNP) | VAF 42/113 reads (37%) | catalogued as COSV53938227, COSV53944270; called by muse, mutect2, varscan2
- SPART | c.1736A>C p.Y579S | Missense Mutation (SNP) | VAF 88/103 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62087673; called by muse, mutect2, varscan2
- SPHKAP | c.3645C>G p.S1215R | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV60869041, COSV60890912; called by muse, mutect2, varscan2
- SPTBN4 | c.5527G>T p.A1843S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.65); catalogued as COSV100152223, COSV58956892; called by muse, mutect2, varscan2
- SSX1 | c.395C>A p.P132Q | Missense Mutation (SNP) | VAF 172/398 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV65356152; called by muse, mutect2, varscan2
- STAB2 | c.4455G>T p.K1485N | Missense Mutation (SNP) | VAF 192/559 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV66344911; called by muse, mutect2, varscan2
- STARD13 | c.2708G>T p.G903V (on ENST00000336934 / NM_001243476.3; = p.G785V on NM_052851.3) | Missense Mutation (SNP) | VAF 148/170 reads (87%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV55229500, COSV99715918; called by muse, mutect2, varscan2
- SYNE1 | c.26134G>A p.V8712I (on ENST00000367255 / NM_182961.4; = p.V8664I on NM_033071.3) | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.718); catalogued as COSV55070882; called by muse, mutect2, varscan2
- SYT10 | c.248G>T p.C83F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV57344223; called by muse, mutect2, varscan2
- THOC2 | c.4270G>T p.V1424L | Missense Mutation (SNP) | VAF 377/1037 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs762461070, COSV55553525; called by muse, mutect2, varscan2
- THOC2 | c.3370T>A p.L1124M | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55553544; called by muse, mutect2, varscan2
- TMTC4 | c.1162C>A p.L388M (on ENST00000376234 / NM_001350577.2; = p.L407M on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV60893357, COSV60893648; called by muse, mutect2, varscan2
- TNR | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 159/391 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); catalogued as COSV54907178; called by muse, mutect2
- TRIM43 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.188); catalogued as COSV55529950, COSV99720013; called by mutect2, varscan2
- TRIP12 | c.4918C>G p.Q1640E | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV52270766; called by muse, mutect2
- TRPC4AP | c.538G>T p.V180F | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as COSV52683371; called by muse, mutect2, varscan2
- TSHR | c.1341C>A p.N447K | Missense Mutation (SNP) | VAF 190/292 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs777698828, COSV53325750, COSV53328811; called by muse, mutect2, varscan2
- TTN | c.12982C>A p.P4328T (on ENST00000591111; = p.P4282T on NM_003319.4) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV60166934; called by muse, mutect2, varscan2
- UBAC1 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as COSV65614522; called by muse, mutect2, varscan2
- UBE3A | c.2491G>T p.G831C | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51669629; called by muse, mutect2, varscan2
- UNC5D | c.1854G>T p.L618F | Missense Mutation (SNP) | VAF 332/553 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV54825551; called by muse, mutect2, varscan2
- USP51 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 23/394 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV72351883; called by muse, mutect2
- WASHC2A | c.3977A>T p.K1326M | Missense Mutation (SNP) | VAF 120/217 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV50955447; called by muse, mutect2, varscan2
- XPO7 | c.2629C>T p.H877Y | Missense Mutation (SNP) | VAF 354/473 reads (75%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV53018950; called by muse, mutect2, varscan2
- ZFHX4 | c.4736C>A p.P1579H | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50927557; called by muse, mutect2
- ZFP37 | c.7G>C p.V3L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as COSV65288155, COSV65288183; called by muse, mutect2, varscan2
- ZNF449 | c.113A>G p.Y38C | Missense Mutation (SNP) | VAF 102/206 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59347804; called by muse, mutect2, varscan2
- ZNF454 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 32/40 reads (80%) | catalogued as COSV60769846; called by muse, mutect2, varscan2
- ZNF521 | c.1499A>T p.H500L | Missense Mutation (SNP) | VAF 103/325 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64130716; called by muse, mutect2, varscan2
- FGR | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GPN3 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 15/249 reads (6%) | called by muse, mutect2
- IGHV3-73 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2
- IGKV3-7 | c.132G>T p.R44S | Missense Mutation (SNP) | VAF 104/262 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- LRRTM1 | c.178del p.A60Rfs*29 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- LYZL6 | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 123/310 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NAPA | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.272); called by muse, mutect2
- NEB | c.4151del p.P1384Lfs*36 | Frame Shift Del (DEL) | VAF 83/249 reads (33%) | called by mutect2, pindel, varscan2
- NR1H4 | c.143del p.G48Dfs*66 (on ENST00000551379 / NM_001206993.2; = p.G38Dfs*66 on NM_005123.4) | Frame Shift Del (DEL) | VAF 31/112 reads (28%) | called by mutect2, pindel, varscan2
- PGAM4 | c.745del p.Q249Rfs*45 | Frame Shift Del (DEL) | VAF 47/143 reads (33%) | called by mutect2, pindel, varscan2
- PNMA5 | c.567del p.W189Cfs*34 | Frame Shift Del (DEL) | VAF 46/155 reads (30%) | called by mutect2, pindel, varscan2
- SERPINF1 | c.283+2_283+3insCT p.X95_splice | Splice Site (INS) | VAF 14/29 reads (48%) | called by mutect2, pindel, varscan2
- TPO | c.2644C>A p.L882M | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- TPTE | c.1324G>T p.V442F (on ENST00000618007 / NM_199261.4; = p.V424F on NM_199259.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.439); called by mutect2, varscan2
- ZNF211 | c.1365_1366del p.C455Wfs*8 (on ENST00000347302 / NM_198855.4; = p.C468Wfs*8 on NM_006385.5) | Frame Shift Del (DEL) | VAF 69/284 reads (24%) | called by pindel, varscan2
- AOC3 | c.1905C>A p.T635= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as COSV53828317; called by muse, mutect2, varscan2
- BTBD3 | c.678T>C p.C226= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as COSV54780933; called by muse, mutect2, varscan2
- BTNL9 | c.675G>A p.V225= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV59798598; called by muse, mutect2, varscan2
- CCSER1 | c.42G>T p.R14= | Silent (SNP) | VAF 15/19 reads (79%) | catalogued as rs562834496, COSV61457981; called by muse, mutect2, varscan2
- CD53 | c.225C>A p.I75= | Silent (SNP) | VAF 36/970 reads (4%) | catalogued as COSV54762730; called by muse, mutect2
- COL22A1 | c.918G>A p.R306= | Silent (SNP) | VAF 207/260 reads (80%) | catalogued as COSV57354553; called by muse, mutect2, varscan2
- DIPK2A | c.588C>T p.N196= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV59858205; called by muse, mutect2, varscan2
- DSG4 | c.2133C>T p.S711= | Silent (SNP) | VAF 61/136 reads (45%) | catalogued as rs766900981, COSV57396295; called by muse, mutect2, varscan2
- FAR2 | c.75G>T p.V25= | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as COSV51728792; called by muse, mutect2, varscan2
- FBXO38 | c.3507G>T p.V1169= (on ENST00000340253 / NM_205836.3; = p.V1094= on NM_030793.5) | Silent (SNP) | VAF 17/182 reads (9%) | catalogued as COSV57030710; called by muse, mutect2, varscan2
- FLNA | c.5347C>T p.L1783= (on ENST00000369850 / NM_001110556.2; = p.L1775= on NM_001456.3) | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV61049197; called by muse, mutect2, varscan2
- GNL3L | c.1359G>A p.T453= | Silent (SNP) | VAF 135/328 reads (41%) | catalogued as COSV60577392; called by muse, mutect2, varscan2
- GRID2 | c.2580C>A p.G860= | Silent (SNP) | VAF 51/67 reads (76%) | catalogued as COSV56249793; called by muse, mutect2, varscan2
- HOXA3 | c.1092C>T p.P364= | Silent (SNP) | VAF 8/9 reads (89%) | catalogued as rs140908739, COSV57828339; called by muse, mutect2, varscan2
- HOXD3 | c.1281C>G p.P427= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV50884399; called by muse, mutect2, varscan2
- HRH2 | c.387G>T p.L129= | Silent (SNP) | VAF 69/96 reads (72%) | catalogued as COSV51574740, COSV51575702; called by muse, mutect2, varscan2
- HS3ST3A1 | c.669G>T p.R223= | Silent (SNP) | VAF 143/197 reads (73%) | catalogued as COSV52378446; called by muse, mutect2, varscan2
- KHNYN | c.424C>T p.L142= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV52162853; called by muse, mutect2, varscan2
- KRBA1 | c.348G>T p.L116= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV55443596; called by muse, mutect2, varscan2
- KRT85 | c.276C>A p.P92= | Silent (SNP) | VAF 96/254 reads (38%) | catalogued as COSV57737945; called by muse, mutect2, varscan2
- LATS1 | c.1518A>G p.P506= | Silent (SNP) | VAF 146/565 reads (26%) | catalogued as rs767012290, COSV53597859; called by muse, varscan2
- LHCGR | c.1482T>C p.S494= | Silent (SNP) | VAF 141/307 reads (46%) | catalogued as COSV54301639; called by muse, mutect2, varscan2
- LMOD2 | c.207G>T p.L69= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV71755797; called by muse, mutect2, varscan2
- LPCAT1 | c.1506A>G p.A502= | Silent (SNP) | VAF 48/162 reads (30%) | catalogued as COSV52040449; called by muse, mutect2, varscan2
- LRFN2 | c.369G>T p.L123= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV57832888; called by muse, mutect2, varscan2
- MAG | c.1764T>G p.G588= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as COSV62702393; called by muse, mutect2, varscan2
- MAGEB3 | c.954C>A p.V318= | Silent (SNP) | VAF 50/87 reads (57%) | catalogued as rs749159690, COSV64397609; called by muse, mutect2, varscan2
- MAN2B1 | c.1251G>T p.A417= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs1055070863, COSV55474615; called by muse, mutect2, varscan2
- MCF2 | c.1998G>C p.L666= | Silent (SNP) | VAF 51/161 reads (32%) | catalogued as COSV58492557; called by muse, varscan2
- MDGA1 | c.2124G>A p.L708= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV51800448; called by muse, mutect2
- MTOR | c.2172C>T p.A724= | Silent (SNP) | VAF 46/190 reads (24%) | catalogued as COSV63876582; called by muse, mutect2, varscan2
- NOVA1 | c.315G>T p.T105= | Silent (SNP) | VAF 73/124 reads (59%) | catalogued as COSV57478942, COSV57485327; called by muse, mutect2, varscan2
- OR4D6 | c.210C>T p.D70= | Silent (SNP) | VAF 57/149 reads (38%) | catalogued as rs758945903, COSV55660723; called by muse, mutect2, varscan2
- OR4K1 | c.456C>T p.G152= | Silent (SNP) | VAF 55/203 reads (27%) | catalogued as rs762768302, COSV53459799; called by muse, mutect2, varscan2
- OR52B2 | c.450C>T p.V150= | Silent (SNP) | VAF 95/295 reads (32%) | catalogued as COSV73209555; called by muse, mutect2, varscan2
- PCDHGA3 | c.1887G>A p.A629= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs1173189539, COSV53966716; called by muse, mutect2, varscan2
- PEAK1 | c.3666G>A p.L1222= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as rs374175949; called by muse, mutect2, varscan2
- PICALM | c.1167G>A p.L389= | Silent (SNP) | VAF 82/152 reads (54%) | catalogued as COSV62673219; called by muse, mutect2, varscan2
- PLXNA3 | c.4629C>A p.L1543= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV63755164; called by muse, mutect2, varscan2
- RTN4 | c.1650G>C p.L550= | Silent (SNP) | VAF 65/191 reads (34%) | catalogued as COSV58272448; called by muse, mutect2, varscan2
- RTP2 | c.303G>T p.T101= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as rs746348051, COSV64079352; called by muse, mutect2
- SDCCAG8 | c.1272G>A p.K424= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV59415460; called by muse, mutect2, varscan2
- SLC1A7 | c.1275C>G p.A425= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as COSV57014340, COSV57016379; called by muse, mutect2, varscan2
- SYNE1 | c.5688T>C p.S1896= (on ENST00000367255 / NM_182961.4; = p.S1903= on NM_033071.3) | Silent (SNP) | VAF 72/146 reads (49%) | catalogued as COSV55070934; called by muse, mutect2, varscan2
- THSD7B | c.2619C>G p.T873= | Silent (SNP) | VAF 57/105 reads (54%) | catalogued as COSV55725807; called by muse, mutect2, varscan2
- TMEM266 | c.126G>A p.L42= | Silent (SNP) | VAF 87/190 reads (46%) | catalogued as COSV66381144; called by muse, mutect2, varscan2
- TPBG | c.702C>T p.P234= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as rs775912512, COSV63882500; called by muse, mutect2, varscan2
- USP25 | c.1281G>A p.T427= | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as rs373634568; called by muse, mutect2, varscan2
- WNK3 | c.3660C>T p.S1220= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as COSV63615487; called by muse, mutect2, varscan2
- ZNF135 | c.153C>A p.V51= | Silent (SNP) | VAF 122/299 reads (41%) | catalogued as COSV57884969; called by muse, mutect2, varscan2
- ATP11C | c.*35C>A | 3'UTR (SNP) | VAF 31/71 reads (44%) | catalogued as COSV100558234; called by muse, mutect2, varscan2
- FN1 | c.3797-1348G>A | Intron (SNP) | VAF 21/76 reads (28%) | catalogued as rs764149816, COSV60561123; called by muse, mutect2, varscan2
- GABRA3 | c.-26-27640C>T | Intron (SNP) | VAF 112/304 reads (37%) | catalogued as COSV64795327; called by muse, mutect2, varscan2
- KIF1B | c.2115+7319G>A | Intron (SNP) | VAF 75/157 reads (48%) | catalogued as rs776976329, COSV99823708; called by muse, mutect2, varscan2
- OFCC1 | n.280G>T | RNA (SNP) | VAF 156/407 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.10303+2627A>T | Intron (SNP) | VAF 48/123 reads (39%) | catalogued as COSV60272740; called by muse, mutect2, varscan2
